TCGA case TCGA-V4-A9EX — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/892e7630-b11e-47bd-987c-327d33258e11

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 55 years; Year of birth: 1956; Vital status: Dead; Days to death: 730 days (2.0 years); Year of death: 2014; Cause of death: Cancer Related.

Diagnoses (2)
1. Epithelioid cell melanoma (the primary disease): ICD-O-3 morphology code: 8771/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 56.0 years (20,447 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 730 days (2.0 years); Sites of involvement: Eye, Choroid.
   Pathology details: Consistent pathology review: Yes; Epithelioid cell percent range: >90%; Extrascleral extension present: No; Measurement type: Echographic; Tumor depth measurement: 15; Tumor shape: Mushroom.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 17.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 7 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fotemustine; Days to treatment start: 424 days (1.2 years); Days to treatment end: 535 days (1.5 years); Number of cycles: 3; Treatment dose: 100 mg/m2; Treatment outcome: No Response; Reason treatment ended: Other.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Clinical Trial Agent; Treatment intent type: Salvage; Days to treatment start: 451 days (1.2 years); Days to treatment end: 714 days (2.0 years); Number of cycles: 6; Treatment outcome: No Response; Reason treatment ended: Other; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Epithelioid cell melanoma), site: Liver. Age at diagnosis: 57.0 years (20,828 days); Days to diagnosis: 381 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (3 entries)
- Day 381 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 381 days (1.0 years).
- Days to follow up: 421 days (1.2 years); Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 421 days (1.2 years).
- Days to follow up: 730 days (2.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: q.

Other clinical attributes
- Comorbidities: Hypothyroidism.
- Timepoint category: Initial Diagnosis; Weight: 77 kg; Height: 163 cm; BMI: 29.
- Eye color: Brown.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9EX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-V4-A9EX-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9EX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9EX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Cause of death: Metastatic Uveal Melanoma.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Epithelioid Cell; Tumor morphology percentage: >90%.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 3 loss; Cytogenetic abnormality type: Chromosome 8q gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 730 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 730 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 381 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9EX-01A-11D-A39V-01): tumor purity 0.93, ploidy 2.09, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3; Gain 8q
- comorbidity: hypothyroid
- days to metastasis: 421
- days to outcome: 732
- days to pharm therapy imaging 1: 532
- days to procedure 1: 7
- diagnosis: melanoma
- disease status at death: Evidence of Disease
- drug name 2: PKC inh
- line of therapy 1: first
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- number cycles 1: 3
- number cycles 2: 6
- performance status scale: Karnofsky
- performance status score: 1
- pharm therapy evaluated by imaging 1: Yes
- pharm therapy imaging type 1: CT
- pharm therapy status 1: treatment change
- pharm therapy status 2: treatment discontinued
- pharm therapy status reason 1: Lack of Response
- pharm therapy status reason 2: Lack of Response
- regimen name 2: phase I COEB
- resection status 1: R0
- smoking status: non-smoker
- staging system: AJCC
- t stage: T4a
- test methodology: aCGH
- test result: high risk
- unresectable 1: no
